Surgical pathology report (de-identified scan), TCGA case TCGA-GF-A4EO, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site ABS - IUPUI, specimen TCGA-GF-A4EO-06A (Metastatic).

[page 1 of 2]
Operative Procedure:
Left axillary node dissection, radical

Specimen Received:
Left axillary contents

Final Pathologic Diagnosis:
Lymph nodes, axillary, left, radial dissection:
Metastatic melanoma.
No morphologic evidence of lymphoma. See note.

The examination of this case material and the preparation of this report were performed by the staff pathologist.

Note:
Repeat flow cytometry was not submitted with this sample. Previous flow cytometry was limited due to low cellularity.

Patient with recent diagnosis of metastatic melanoma in axilla. Immunostains for melanoma are not repeated, since the morphologic findings are compatible with the diagnosis of melanoma.

Gross Description:

The specimen is received in formalin labeled with the patient's name and labeled "left axillary contents" and consists of an irregular lobulated rubbery mass, which has dimensions of 15.2 x 10.5 x 6.5 cm. The external surface is gray-yellow to red-brown, smooth and glistening to mostly shaggy. The mass is serially sectioned to reveal a pink-tan fleshy focally hemorrhagic, focally degenerated and focally fibrous cut surface.

Also in the same container is an aggregate of irregular, ragged, gray-yellow lobulated focally cauterized fibrofatty tissue, which has dimensions of 15.0 x 13.0 x 4.5 cm. The fat is serially sectioned to reveal a gray yellow to white, lobulated and glistening cut surface that is remarkable for four ill defined, fleshy foci which range from 0.8 to 3.2 cm in greatest dimension. These foci may represent lymph nodes. Also, this fat is remarkable for two gray-yellow to red-brown, hemorrhagic and degenerated nodules, which have greatest dimensions of 1.2 and 1.8 cm.

Representative sections are submitted as labeled:

- 1-2 mass;
- 3-4 fleshy foci/? lymph nodes;
- 5-6 hemorrhagic and degenerated nodules.

1CD-0-3

Melanoma, Nos 8720/3

Site: lymph node, axillary C77.3

hw
9/25/12

[page 2 of 2]
Microscopic Description:

Histologic sections show portions of lymph nodes effaced by metastatic melanoma.

Select lymph nodes show preserved nodal architecture with primary and secondary follicles, open sinuses and paracortical expansion. Additional lymph node is entirely necrotic.

Immunohistochemical studies show appropriate compartmentalization of B- and T-cells (CD20, CD5 and CD3 immunostains). Plasma cells are polyclonal as evidenced by kappa and lambda light chain immunostains. Cyclin D1 is negative in lymphoid cells. All controls stain appropriately.

END OF REPORT

Taken:

) Gender: F

W
9/18/12

Source: NCI Genomic Data Commons file 276c1ddc-d3bc-48c2-a131-defbaba10057 (TCGA-GF-A4EO.D0E07D23-49D0-4B7B-9F44-62685191A272.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).